Gene-level copy-number profile of tumor specimen ALCH-AENP-TTP1-A from ALCHEMIST case ALCH-AENP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,757 days).
Specimen ALCH-AENP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 49640fd5-fdf4-4ab8-9950-661bd26945c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AENP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/4d477a55-52c1-4625-941a-5b9e4d9ebb65

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 18,654; copy number 2: 31,182; copy number 3: 6,148; copy number 4: 2,126; copy number 5: 121; copy number 6: 79; copy number 7: 3; copy number 8: 3; copy number 11: 10; copy number 20: 25.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,043,736–16,057,308, 1 gene: CLCNKB.
- chr1:109,249,539–109,275,751, 1 gene: CELSR2.
- chr2:242,047,695–242,084,233, 1 gene (within-gene range 0–1): LINC01880.
- chr4:68,537,184–68,568,527, 1 gene (within-gene range 0–1): UGT2B17.
- chr4:128,069,014–128,069,612, 1 gene (within-gene range 0–1): AC099340.1.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr7:128,850,162–128,862,626, 1 gene (within-gene range 0–1): FLNC-AS1.
- chr7:149,191,043–149,191,223, 1 gene: AC004890.1.
- chr12:125,056,359–125,056,581, 1 gene: AC122688.1.
- chr14:49,598,761–49,629,890, 7 genes (within-gene range 0–1): LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, AL139099.2.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.
- chr22:41,938,737–41,947,152, 1 gene: CENPM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 241 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–594,768, 11 genes, copy number 8–11 (within-gene range 4–11): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1.
- chr1:228,073,909–228,076,550, 1 gene, copy number 5: LINC02809.
- chr1:228,555,793–228,626,027, 10 genes, copy number 5: RNA5SP19, RNA5SP162, RNA5S1, RNA5S2, RNA5S3, RNA5S4, RNA5S5, RNA5S6, RNA5S7, RNA5S8.
- chr3:181,952,343–182,921,629, 15 genes, copy number 5 (within-gene range 4–5): LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2.
- chr4:3,901,566–3,955,432, 6 genes, copy number 6 (within-gene range 4–6): OR7E162P, AC147876.1, AC226119.1, AC226119.2, ALG1L7P, FAM86EP.
- chr4:4,048,211–4,107,583, 3 genes, copy number 5: AC116562.3, RPS3AP16, AC116562.2.
- chr4:4,156,522–4,157,443, 1 gene, copy number 6: OR7E99P.
- chr5:45,035,199–45,895,970, 5 genes, copy number 5: AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr9:32,727,069–34,774,466, 97 genes, copy number 5–6 (broad region; genes not listed).
- chr9:39,983,793–40,106,611, 1 gene, copy number 5 (within-gene range 4–5): AL772307.1.
- chr9:40,105,822–41,355,538, 41 genes, copy number 5–6: AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1, AL353626.2, MIR1299, FRG1HP, PGM5P2, AL353763.2, AL353763.1, BX255923.1, BX255923.2, FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6.
- chr9:64,810,865–65,573,495, 11 genes, copy number 6: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA.
- chr9:120,388,869–120,714,470, 2 genes, copy number 5: CDK5RAP2, MEGF9.
- chr14:105,583,731–105,588,395, 1 gene, copy number 7: IGHA2.
- chr16:848,525–849,065, 1 gene, copy number 5: AL031008.1.
- chr17:17,674,026–17,677,688, 3 genes, copy number 5: SMCR2, AC020558.3, AC020558.4.
- chr20:64,290,187–64,327,972, 3 genes, copy number 5: CICP4, LINC00266-1, AL137028.1.
- chr22:18,846,811–18,861,049, 2 genes, copy number 7: AC008132.1, BCRP7.
- chr22:49,213,911–50,012,659, 27 genes, copy number 8–20: RPL35P8, Z82202.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL.

Autosomal genes at a single copy (total copy number 1): 16,645. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
